Gene-level copy-number profile of tumor specimen C3N-02929-01 (profiled together with C3N-02929-02) from CPTAC case C3N-02929, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA3; Tumor grade: G2; Age at diagnosis: 58.1 years (21,205 days).
Specimen C3N-02929-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a23b6da-70b7-4887-bfab-fa47192be9dd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02929-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,857 have no estimate.
https://portal.gdc.cancer.gov/files/d190085e-5ce1-45e5-bf6c-3d075c59041f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 302; copy number 1: 17,610; copy number 2: 32,911; copy number 3: 6,687; copy number 4: 827; copy number 5: 422; copy number 6: 7.

Homozygous deletions (total copy number 0; autosomes only): 146 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,498,133–22,552,156, 144 genes (within-gene range 0–1) (broad region; genes not listed).
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 429 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:31,053,565–45,895,970, 242 genes, copy number 5 (broad region; genes not listed).
- chr17:59,847,438–60,666,280, 39 genes, copy number 5 (within-gene range 3–5): RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D.
- chr17:70,312,831–73,092,712, 20 genes, copy number 5–6 (within-gene range 4–6): AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11.
- chr17:73,067,870–76,121,576, 128 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
